CCDI case PBCGXF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/253ba2ab-fd7a-4b28-af47-f4c71d6e6481

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,603 days).

Biospecimens (3 samples)
- Sample 0DRMOH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRMOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRMON: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
